Somatic mutation profile of tumor specimen TCGA-CN-4734-01A (aliquot TCGA-CN-4734-01A-01D-1434-08) from TCGA case TCGA-CN-4734, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cheek mucosa; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 70.5 years (25,753 days).
Specimen TCGA-CN-4734-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ea05222-7a07-45b4-9b80-d7df51c44198.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-4734-10A (Blood Derived Normal), aliquot TCGA-CN-4734-10A-01D-1434-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3600cd57-7ae2-4581-a6bd-d8379a04def2

The open-access MAF lists 155 somatic variants for this specimen: 107 protein-altering or splice-affecting, 46 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 91, Silent 46, Nonsense Mutation 10, Splice Site 3, Frame Shift Del 2, Frame Shift Ins 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYH7 | c.1231G>A p.V411I | Missense Mutation (SNP) | VAF 159/258 reads (62%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as rs730880868, CM032602, COSV62517652; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCB6 | c.912G>A p.W304* | Nonsense Mutation (SNP) | VAF 20/129 reads (16%) | catalogued as COSV99522168; called by muse, mutect2, varscan2
- AC098582.1 | c.1244C>G p.S415* | Nonsense Mutation (SNP) | VAF 24/81 reads (30%) | catalogued as COSV99985933, COSV99986017; called by muse, mutect2, varscan2
- ADGRB3 | c.4390G>A p.A1464T | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs764036367, COSV53246764; called by muse, mutect2, varscan2
- ANO4 | c.1447A>G p.N483D (on ENST00000392977 / NM_001286615.2; = p.N448D on NM_178826.4) | Missense Mutation (SNP) | VAF 39/230 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as rs750919999, COSV100153620; called by muse, mutect2, varscan2
- ASXL3 | c.2251G>C p.E751Q | Missense Mutation (SNP) | VAF 83/320 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.78); catalogued as COSV99326239; called by muse, mutect2, varscan2
- BCO1 | c.343C>G p.H115D | Missense Mutation (SNP) | VAF 78/281 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.959); catalogued as COSV99258594; called by muse, mutect2, varscan2
- BCOR | c.3124G>A p.E1042K | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as rs1178525455, COSV60718432; called by muse, mutect2, varscan2
- BRD8 | c.3058G>C p.E1020Q | Missense Mutation (SNP) | VAF 52/213 reads (24%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV99648996; called by muse, mutect2, varscan2
- CACNA1D | c.5942G>A p.W1981* (on ENST00000350061 / NM_001128840.3; = p.W2001* on NM_000720.4) | Nonsense Mutation (SNP) | VAF 26/110 reads (24%) | catalogued as COSV99859746; called by muse, mutect2, varscan2
- CACNA1S | c.164C>T p.T55M | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as rs549107212, COSV62940261; called by muse, mutect2, varscan2
- CASP8 | c.1393C>T p.Q465* (on ENST00000432109 / NM_033355.3; = p.Q482* on NM_001228.4) | Nonsense Mutation (SNP) | VAF 38/80 reads (48%) | catalogued as COSV51844901; called by muse, mutect2, varscan2
- CBR3 | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); catalogued as COSV99289883; called by muse, mutect2
- CLSPN | c.758C>T p.S253F | Missense Mutation (SNP) | VAF 62/126 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0.055); catalogued as COSV99231433; called by muse, mutect2, varscan2
- CNTNAP3 | c.2158C>G p.Q720E | Missense Mutation (SNP) | VAF 65/571 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.354); catalogued as COSV99904917; called by muse, mutect2
- COL5A1 | c.344T>C p.F115S | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.81); catalogued as COSV100880507; called by muse, mutect2, varscan2
- CPM | c.1140G>C p.E380D | Missense Mutation (SNP) | VAF 39/164 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs1191454154, COSV100615250; called by muse, mutect2, varscan2
- CRB3 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs751295212, COSV100375418; called by muse, mutect2
- CYP11B1 | c.1304G>A p.G435D | Missense Mutation (SNP) | VAF 66/193 reads (34%) | SIFT tolerated (0.6); PolyPhen benign (0.198); catalogued as COSV52828773, COSV99455740; called by muse, mutect2, varscan2
- CYP2R1 | c.434G>C p.R145P | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100584987, COSV58129104; called by muse, mutect2, varscan2
- DAB2 | c.1322G>C p.R441T | Missense Mutation (SNP) | VAF 48/212 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100298276; called by muse, mutect2, varscan2
- DDX60L | c.2444C>T p.T815M | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as rs541986385, COSV52711708, COSV99488302; called by muse, mutect2, varscan2
- DIP2A | c.2597C>T p.S866L | Missense Mutation (SNP) | VAF 42/184 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as rs368841415; called by muse, mutect2, varscan2
- DNAJC18 | c.59G>A p.R20K | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.899); catalogued as COSV100122192; called by muse, mutect2, varscan2
- DNM3 | c.1939G>C p.E647Q (on ENST00000355305 / NM_001350206.2; = p.E641Q on NM_015569.5) | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.146); catalogued as COSV100798605; called by muse, mutect2, varscan2
- EEF1A1 | c.802G>C p.E268Q | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV100303411, COSV58550679; called by muse, mutect2, varscan2
- EGR1 | c.308-1G>C p.X103_splice | Splice Site (SNP) | VAF 93/427 reads (22%) | catalogued as COSV99525577; called by muse, mutect2, varscan2
- EIF4G2 | c.2221A>G p.I741V | Missense Mutation (SNP) | VAF 46/181 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as rs925499061, COSV101151095; called by muse, mutect2, varscan2
- EPHA2 | c.1256C>G p.S419* | Nonsense Mutation (SNP) | VAF 42/83 reads (51%) | catalogued as COSV100626261; called by muse, mutect2, varscan2
- EPHA5 | c.2195A>C p.D732A | Missense Mutation (SNP) | VAF 52/245 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as COSV99900886; called by muse, mutect2, varscan2
- ERAP1 | c.536C>T p.S179L | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.648); catalogued as COSV99701236; called by muse, mutect2, varscan2
- ERBB4 | c.2139G>C p.L713F | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV53524670, COSV99631378; called by muse, mutect2, varscan2
- F2RL1 | c.254T>C p.V85A | Missense Mutation (SNP) | VAF 70/292 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99688883; called by muse, mutect2, varscan2
- FAM221B | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 53/126 reads (42%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.476); catalogued as COSV100941450; called by muse, mutect2, varscan2
- FBXO31 | c.1261G>A p.G421S | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV100291595; called by muse, mutect2, varscan2
- FCGBP | c.4310G>A p.G1437E | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs587620216, COSV55433989; called by muse, mutect2, varscan2
- FCRLB | c.262C>T p.R88W | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs201479109, COSV100396357, COSV61060556; called by muse, mutect2, varscan2
- HOXB4 | c.618C>G p.I206M | Missense Mutation (SNP) | VAF 70/316 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs774903494, COSV100203837; called by muse, mutect2, varscan2
- INSYN2A | c.172G>T p.E58* | Nonsense Mutation (SNP) | VAF 61/269 reads (23%) | catalogued as COSV99732216; called by muse, mutect2, varscan2
- IRF2 | c.695-1G>C p.X232_splice | Splice Site (SNP) | VAF 32/115 reads (28%) | catalogued as COSV101165901; called by muse, mutect2, varscan2
- ITSN2 | c.1444G>T p.V482F | Missense Mutation (SNP) | VAF 38/177 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as COSV100744087; called by muse, mutect2, varscan2
- KIF22 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.202); catalogued as COSV99361441; called by muse, mutect2, varscan2
- KLHL13 | c.1601G>T p.G534V | Missense Mutation (SNP) | VAF 189/391 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV99452441; called by muse, mutect2, varscan2
- KRTCAP3 | c.263G>T p.R88L | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV99274997, COSV99275253; called by muse, mutect2, varscan2
- LAMB4 | c.328G>T p.G110C | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99225385; called by muse, mutect2, varscan2
- LILRA4 | c.106G>A p.G36S | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV52493479, COSV99393346; called by muse, mutect2, varscan2
- LRP6 | c.3950C>T p.S1317L | Missense Mutation (SNP) | VAF 41/204 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.955); catalogued as COSV99744307; called by muse, mutect2, varscan2
- LRRC47 | c.898G>C p.D300H | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV100989360; called by muse, mutect2, varscan2
- MAD1L1 | c.216G>A p.M72I | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV99767366; called by muse, mutect2, varscan2
- MOGS | c.2107G>A p.D703N | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV99270748; called by muse, mutect2, varscan2
- MRGPRF | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.599); catalogued as rs745589039, COSV100307783, COSV100307916; called by muse, varscan2
- MTA3 | c.870C>A p.F290L | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV100882829; called by muse, mutect2, varscan2
- MYH13 | c.3802G>A p.E1268K | Missense Mutation (SNP) | VAF 52/216 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as rs866115089, COSV52830787; called by muse, mutect2, varscan2
- MYO15A | c.485G>A p.R162H | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as rs1194603466, COSV52757958; called by muse, mutect2, varscan2
- NOP14 | c.1597G>C p.E533Q | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV100054884; called by muse, mutect2, varscan2
- NOS2 | c.1474C>A p.Q492K | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100569860; called by muse, varscan2
- NR5A2 | c.425G>A p.R142H (on ENST00000367362 / NM_205860.3; = p.R96H on NM_003822.5) | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746191281, COSV52648171; called by muse, mutect2, varscan2
- NRG2 | c.449G>T p.R150L | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.488); catalogued as rs754211202, COSV99181058; called by mutect2, varscan2
- OR52B6 | c.817C>A p.P273T | Missense Mutation (SNP) | VAF 85/340 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs760824626, COSV61448112, COSV61448371; called by muse, mutect2
- PCBP3 | c.843G>C p.M281I | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV101234351, COSV101234373; called by muse, mutect2, varscan2
- PCDHB12 | c.2125G>A p.V709M | Missense Mutation (SNP) | VAF 60/322 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); catalogued as rs199658197, COSV99507739; called by muse, mutect2, varscan2
- PDE1A | c.190G>C p.E64Q | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100116115; called by muse, mutect2, varscan2
- PDZRN3 | c.2240C>T p.P747L | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs750579131, COSV99731728; called by muse, mutect2
- PHLDB1 | c.2416G>C p.E806Q | Missense Mutation (SNP) | VAF 49/205 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100616747; called by muse, mutect2, varscan2
- PIK3C2G | c.1156C>G p.Q386E | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV56806148; called by muse, mutect2
- PLEC | c.12817G>A p.V4273M (on ENST00000322810 / NM_201380.4; = p.V4163M on NM_000445.5) | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs749212061, COSV59628398; called by muse, mutect2, varscan2
- PLEKHA4 | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as rs556472997, COSV99613150; called by muse, mutect2, varscan2
- PPP5C | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 51/238 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1320561842, COSV50141579; called by muse, mutect2, varscan2
- PRL | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.63); PolyPhen benign (0.018); catalogued as rs1167633349, COSV60592097; called by muse, mutect2, varscan2
- PURB | c.82G>T p.E28* | Nonsense Mutation (SNP) | VAF 8/32 reads (25%) | catalogued as COSV101194994; called by muse, mutect2
- RAP1B | c.35G>A p.G12E | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51667594; called by muse, mutect2, varscan2
- RASGRF2 | c.2663C>A p.A888E | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.772); catalogued as COSV99430122; called by muse, mutect2, varscan2
- RBM43 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 50/185 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as COSV100508635; called by muse, mutect2, varscan2
- RECQL | c.1378C>G p.Q460E | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99556736; called by muse, mutect2, varscan2
- RP1L1 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.173); catalogued as rs749294164, COSV100262332; called by muse, mutect2, varscan2
- RPA1 | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1238804059, COSV54610917, COSV99628219; called by muse, mutect2, varscan2
- RSPO2 | c.699C>A p.S233R | Missense Mutation (SNP) | VAF 24/189 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV52649812, COSV99410257; called by muse, mutect2, varscan2
- RUNDC3B | c.1334G>C p.S445T | Missense Mutation (SNP) | VAF 61/233 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100353798; called by muse, mutect2, varscan2
- SALL3 | c.2276G>A p.R759H | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1213859896, COSV73305925; called by muse, mutect2, varscan2
- SATB1 | c.1718C>T p.A573V | Missense Mutation (SNP) | VAF 40/162 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.392); catalogued as rs564141224, COSV58669497, COSV58672813; called by muse, mutect2, varscan2
- SGPP1 | c.1120G>C p.V374L | Missense Mutation (SNP) | VAF 100/327 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV99905979; called by muse, mutect2, varscan2
- SLC23A2 | c.1229C>A p.P410H | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs765478407, COSV100594806; called by mutect2, varscan2
- SLC28A2 | c.1855C>G p.Q619E | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV61663279, COSV61663581; called by muse, mutect2, varscan2
- SP4 | c.250C>T p.Q84* | Nonsense Mutation (SNP) | VAF 31/102 reads (30%) | catalogued as COSV99754966; called by muse, mutect2, varscan2
- SPRY1 | c.533A>G p.K178R | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs754426228, COSV100201900; called by muse, mutect2, varscan2
- SSH2 | c.2295G>C p.Q765H | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV99282885; called by muse, mutect2, varscan2
- SYCP3 | c.379C>G p.Q127E | Missense Mutation (SNP) | VAF 59/142 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.093); catalogued as COSV99901748; called by muse, mutect2, varscan2
- TADA3 | c.707-1G>A p.X236_splice | Splice Site (SNP) | VAF 68/288 reads (24%) | catalogued as COSV100113108; called by muse, mutect2, varscan2
- TG | c.5587C>A p.Q1863K | Missense Mutation (SNP) | VAF 39/209 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.138); catalogued as COSV99602858; called by muse, mutect2, varscan2
- THEMIS | c.403C>A p.Q135K | Missense Mutation (SNP) | VAF 77/290 reads (27%) | SIFT tolerated (0.85); PolyPhen benign (0.005); catalogued as rs765387427, COSV100965532, COSV64070629; called by muse, mutect2, varscan2
- TM9SF3 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.532); catalogued as COSV100951881; called by muse, mutect2, varscan2
- TMTC3 | c.2501C>G p.S834* | Nonsense Mutation (SNP) | VAF 102/229 reads (45%) | catalogued as COSV99898638; called by muse, mutect2, varscan2
- TOGARAM1 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 162/271 reads (60%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100753262; called by muse, mutect2, varscan2
- TPRA1 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.965); catalogued as rs770480334, COSV99952286; called by muse, mutect2, varscan2
- TRIM35 | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.736); catalogued as COSV100542852; called by muse, mutect2, varscan2
- TTN | c.78214G>A p.E26072K (on ENST00000591111; = p.E18648K on NM_003319.4) | Missense Mutation (SNP) | VAF 31/170 reads (18%) | PolyPhen benign (0.116); catalogued as COSV100626904; called by muse, mutect2, varscan2
- TUBA3C | c.862G>A p.V288M | Missense Mutation (SNP) | VAF 52/221 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.468); catalogued as rs747244144, COSV67138980, COSV67140232; called by muse, mutect2, varscan2
- UNC13C | c.567G>C p.K189N | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV99512797, COSV99522335; called by muse, mutect2, varscan2
- USP44 | c.763C>T p.Q255* | Nonsense Mutation (SNP) | VAF 34/263 reads (13%) | catalogued as COSV99312018; called by muse, mutect2, varscan2
- ZBTB37 | c.1012C>A p.P338T | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.047); catalogued as COSV100875316; called by muse, mutect2, varscan2
- ZC3H11A | c.2267G>A p.R756Q | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.144); catalogued as rs774268525, COSV59748879, COSV59749193; called by muse, mutect2, varscan2
- ZFYVE16 | c.2827C>G p.Q943E | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100566624; called by muse, mutect2, varscan2
- ZNF292 | c.1289G>A p.C430Y | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100371040; called by muse, mutect2, varscan2
- ZSWIM4 | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.385); catalogued as rs1292524940, COSV54319942, COSV54321177; called by mutect2, varscan2
- ARAP2 | c.3202dup p.I1068Nfs*41 | Frame Shift Ins (INS) | VAF 60/259 reads (23%) | called by mutect2, pindel, varscan2
- ITGB6 | c.1313_1355del p.V438Afs*11 | Frame Shift Del (DEL) | VAF 22/76 reads (29%) | called by mutect2, pindel
- PFKFB4 | c.570_574del p.F191Efs*4 | Frame Shift Del (DEL) | VAF 27/102 reads (26%) | called by mutect2, pindel, varscan2
- ABHD15 | c.1077C>T p.D359= | Silent (SNP) | VAF 13/122 reads (11%) | catalogued as rs747429685, COSV100213051; called by muse, mutect2, varscan2
- ANO2 | c.693G>A p.S231= (on ENST00000356134 / NM_001278597.3; = p.S235= on NM_001278596.3) | Silent (SNP) | VAF 18/122 reads (15%) | catalogued as rs746073538, COSV100502077, COSV59033970; called by muse, mutect2, varscan2
- CACNG2 | c.732G>T p.T244= | Silent (SNP) | VAF 41/182 reads (23%) | catalogued as rs756630130, COSV100269035, COSV55642559; called by muse, mutect2, varscan2
- CARD14 | c.2901C>T p.Y967= | Silent (SNP) | VAF 4/11 reads (36%) | called by muse, mutect2, varscan2
- CCDC183 | c.1344C>T p.L448= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as rs756390271, COSV100273685; called by muse, mutect2, varscan2
- DNMT3A | c.1641C>T p.L547= | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as rs1355927798, COSV99264172; called by muse, mutect2, varscan2
- DST | c.12327G>A p.T4109= (on ENST00000361203 / NM_001374722.1; = p.T1697= on NM_015548.5) | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs763102936, COSV99759295, COSV99759333; called by muse, mutect2, varscan2
- DYNC1H1 | c.12504G>A p.R4168= | Silent (SNP) | VAF 50/97 reads (52%) | catalogued as COSV100795324; called by muse, mutect2, varscan2
- EFNA3 | c.363G>A p.K121= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV100860869; called by muse, mutect2, varscan2
- FAM151A | c.54C>A p.G18= | Silent (SNP) | VAF 121/226 reads (54%) | catalogued as COSV100157084; called by muse, mutect2, varscan2
- FAM90A1 | c.1203C>T p.N401= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as rs769810148, COSV56714363; called by muse, mutect2, varscan2
- FBXO38 | c.1416T>G p.A472= | Silent (SNP) | VAF 21/75 reads (28%) | catalogued as COSV99693883; called by muse, mutect2, varscan2
- GCK | c.1098C>T p.I366= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV99790102; called by muse, mutect2, varscan2
- H1-4 | c.156G>A p.K52= | Silent (SNP) | VAF 7/68 reads (10%) | catalogued as rs753419578, COSV99175362; called by muse, mutect2, varscan2
- HHIPL1 | c.849C>T p.S283= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as rs750868366, COSV58090246; called by muse, mutect2, varscan2
- IDH3A | c.531G>A p.K177= | Silent (SNP) | VAF 33/156 reads (21%) | catalogued as COSV100211004; called by muse, mutect2, varscan2
- IFFO1 | c.876G>A p.L292= | Silent (SNP) | VAF 34/92 reads (37%) | catalogued as COSV100350756; called by muse, mutect2, varscan2
- ITGAD | c.27G>A p.L9= | Silent (SNP) | VAF 67/238 reads (28%) | catalogued as COSV101210563; called by muse, varscan2
- KCNQ3 | c.1818C>G p.A606= | Silent (SNP) | VAF 62/150 reads (41%) | catalogued as COSV101196374; called by muse, mutect2, varscan2
- KRT12 | c.1302C>T p.D434= | Silent (SNP) | VAF 21/97 reads (22%) | catalogued as COSV52431755; called by muse, mutect2, varscan2
- MAST3 | c.2334G>A p.L778= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as rs764582359, COSV99446194; called by muse, mutect2, varscan2
- MED13L | c.987C>T p.T329= | Silent (SNP) | VAF 15/108 reads (14%) | catalogued as COSV99929977; called by muse, mutect2, varscan2
- MYF6 | c.366C>T p.A122= | Silent (SNP) | VAF 21/141 reads (15%) | catalogued as COSV99952923; called by muse, mutect2, varscan2
- NFAT5 | c.294C>T p.T98= | Silent (SNP) | VAF 100/422 reads (24%) | catalogued as COSV100591158; called by muse, mutect2, varscan2
- NIPAL4 | c.555C>T p.Y185= | Silent (SNP) | VAF 41/158 reads (26%) | catalogued as rs777992589, COSV100357289; called by muse, mutect2, varscan2
- NIPBL | c.3105A>G p.P1035= | Silent (SNP) | VAF 39/148 reads (26%) | catalogued as COSV99242340; called by muse, mutect2, varscan2
- NRDE2 | c.582C>T p.C194= | Silent (SNP) | VAF 25/167 reads (15%) | catalogued as rs749327168, COSV100583623; called by muse, mutect2, varscan2
- NUP93 | c.2382C>G p.T794= | Silent (SNP) | VAF 30/72 reads (42%) | catalogued as COSV100360460; called by muse, mutect2, varscan2
- OR10H1 | c.666C>T p.I222= | Silent (SNP) | VAF 24/168 reads (14%) | catalogued as rs1048040148, COSV58472060; called by muse, mutect2, varscan2
- OR10W1 | c.360G>A p.P120= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as rs200368241; called by muse, mutect2, varscan2
- OR7G1 | c.405C>T p.L135= | Silent (SNP) | VAF 30/128 reads (23%) | catalogued as rs756099833, COSV99528763; called by muse, mutect2, varscan2
- OVCH1 | c.1527G>T p.T509= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as COSV58965393, COSV58968345; called by muse, mutect2, varscan2
- PHKB | c.2169C>G p.P723= | Silent (SNP) | VAF 29/177 reads (16%) | catalogued as COSV100068343; called by muse, mutect2, varscan2
- PHLDB2 | c.3417A>G p.V1139= (on ENST00000393925 / NM_001134439.2; = p.V1096= on NM_145753.2) | Silent (SNP) | VAF 28/122 reads (23%) | catalogued as rs768412064, COSV67313401; called by muse, mutect2, varscan2
- PSG11 | c.60C>G p.L20= | Silent (SNP) | VAF 54/282 reads (19%) | catalogued as COSV100106113; called by muse, mutect2, varscan2
- SEC14L2 | c.843C>T p.S281= | Silent (SNP) | VAF 32/149 reads (21%) | catalogued as rs957935570, COSV57240286; called by muse, mutect2, varscan2
- SEMA4C | c.2406C>T p.L802= | Silent (SNP) | VAF 54/210 reads (26%) | catalogued as rs766255435, COSV59691090; called by muse, mutect2, varscan2
- SPATA25 | c.117G>A p.V39= | Silent (SNP) | VAF 43/166 reads (26%) | catalogued as rs1243264448, COSV99510112; called by muse, mutect2, varscan2
- SPDYE3 | c.1482G>A p.P494= | Silent (SNP) | VAF 37/163 reads (23%) | catalogued as rs758269161, COSV60107012, COSV60107718; called by muse, mutect2, varscan2
- TJP1 | c.2328T>C p.N776= | Silent (SNP) | VAF 34/136 reads (25%) | catalogued as COSV100633105; called by muse, mutect2, varscan2
- TMEM161A | c.1362C>T p.L454= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV99365568; called by muse, mutect2
- TNFRSF1B | c.435G>A p.P145= | Silent (SNP) | VAF 35/56 reads (63%) | catalogued as rs747434014, COSV100884197; called by muse, mutect2, varscan2
- TNFSF11 | c.876G>A p.E292= | Silent (SNP) | VAF 56/251 reads (22%) | catalogued as COSV53479615; called by muse, mutect2, varscan2
- TPTE | c.391C>T p.L131= (on ENST00000618007 / NM_199261.4; = p.L113= on NM_199259.4) | Silent (SNP) | VAF 25/115 reads (22%) | called by muse, mutect2, varscan2
- ZNF283 | c.285G>A p.R95= | Silent (SNP) | VAF 40/130 reads (31%) | catalogued as COSV100161440; called by muse, mutect2, varscan2
- ZNF521 | c.2667C>T p.D889= | Silent (SNP) | VAF 29/106 reads (27%) | catalogued as COSV100833219; called by muse, mutect2, varscan2
- NEBL | c.164+26028C>T | Intron (SNP) | VAF 37/155 reads (24%) | catalogued as COSV65798749; called by muse, mutect2, varscan2
- OSGIN1 | n.414C>T | RNA (SNP) | VAF 44/142 reads (31%) | catalogued as rs568526491, COSV100652449; called by muse, mutect2, varscan2
